Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JP, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JP-01A (Primary Tumor).

[page 1 of 2]
Requesting Doctor's Information:

Deliver To

ICD-0-3

Carcinoma, adrenal cortical

8370/3

Site @ Adrenal Gland, cortex

C74.0

gld 1/36/13

Received

SPECIMEN TYPE: Adrenal

CLINICAL NOTES:

Non-functional left adrenal tumour.

MACROSCOPIC:

"Left adrenal gland". The specimen consists of an adrenal gland, 504 g and 110 x 110 x 85 mm. The adrenal gland is largely replaced by a 100mm tumour. The tumour is multinodular and has a variable cut surface with solid tan lobules, yellow/orange areas, and areas of haemorrhage, cystic change and necrosis. The tumour appears at least partially encapsulated and there is no macroscopic evidence of invasion. A small amount of uninvolved adrenal is identified at the periphery of the tumour.

A1/A2 - Tumour with adjacent uninvolved adrenal gland.

A3 - A6: Central tumour.

A7 - A10: Tumour with overlying capsule.

MICROSCOPIC:

The left adrenal tumour is an adrenal cortical carcinoma (Weiss criteria). The tumour is composed of polygonal cells showing a predominantly diffuse, sheet-like growth pattern with areas of myxoid degeneration which are divided in areas by fibrous septa. The cells have abundant eosinophilic cytoplasm with a few scattered clear cells present. The nuclei are enlarged and pleomorphic with coarse chromatin and prominent nucleoli. Mitoses are readily identified (13/50hpf), including atypical forms, and there are broad areas of necrosis and haemorrhage. No vascular invasion is identified. While the tumour does extend to the adrenal capsule it appears to be confined to the adrenal gland and local excision is complete.

Immunohistochemistry shows positive staining for inhibin, calretinin and Melan A and negative staining for chromogranin.

The morphological features and immunohistochemical profile are in keeping with an adrenal cortical carcinoma.

SUMMARY:

Left adrenal gland: Adrenal cortical carcinoma.

STAGE: II (pT2, NX, MX). (AJCC Staging, 7th Edition)

ADDITIONAL REPORT

The tumour has a Weiss score of 6.

Ki67 stains between 25-36% of tumour cells in the most proliferative areas.

KdS.

ANATOMICAL PATHOLOGY

ANATOMICAL PATHOLOGY

COPIES

[page 2 of 2]
Requesting Doctor's Information:

SPECIMEN TYPE: Adrenal

REPORTING PATHOLOGIS

(Electronic Signature)

HISTOPATHOLOGY

ANATOMICAL

Criteria	lw 11/23/13	Yes	No

Source: NCI Genomic Data Commons file ebeecbf8-79ae-4c78-8acd-4e9e0d6309a9 (TCGA-OR-A5JP.E7B0A3CF-35A3-433C-AF76-DB3E28DA6A46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).